Gene-level copy-number profile of tumor specimen TCGA-2G-AAGS-01A from TCGA case TCGA-2G-AAGS, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 39.2 years (14,312 days).
Specimen TCGA-2G-AAGS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.de61c881-1a5a-4530-86cf-ab51742c43c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AAGS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5834649b-96f6-4223-acd2-0c91bd7d7eba

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 170; copy number 2: 18,976; copy number 3: 33,352; copy number 4: 3,251; copy number 5: 2,569; copy number 6: 453; copy number 7: 962; copy number 25: 84.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AAGS-01A-11D-A42X-01): tumor purity 0.88, ploidy 2.91, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,046 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–38,589,812, 864 genes, copy number 7 (broad region; genes not listed).
- chr12:68,575,858–80,680,273, 182 genes, copy number 7–25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 170. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
